Somatic mutation profile of cancer-model specimen HCM-BROD-0681-C71-85R (Adherent Cell Line, passage 10; aliquot HCM-BROD-0681-C71-85R-01D-A83U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0681-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.2 years (18,343 days).
Specimen HCM-BROD-0681-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04520d99-1004-4417-b678-b81928d21f75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0681-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0681-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3df53615-6deb-4a46-9099-4557450a52a8

The open-access MAF lists 1,166 somatic variants for this specimen: 780 protein-altering or splice-affecting, 349 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 696, Silent 349, Nonsense Mutation 39, Splice Site 27, Intron 20, Splice Region 11, RNA 6, Frame Shift Del 5, 5'Flank 4, 5'UTR 3, 3'Flank 2, 3'UTR 2.

Variants (750 of 1,166; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR2 | c.853-1G>A p.X285_splice | Splice Site (SNP) | VAF 122/251 reads (49%) | catalogued as rs1085307267, CS085038, CS1513975, COSV101001390; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 5977/6801 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 142/321 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TCF3 | c.1823-508G>A | Intron (SNP) | VAF 340/1005 reads (34%) | catalogued as rs879255271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3307A>G p.I1103V | Missense Mutation (SNP) | VAF 241/514 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as rs746693787; called by muse, mutect2, varscan2
- ABI1 | c.719+1G>A p.X240_splice | Splice Site (SNP) | VAF 129/129 reads (100%) | catalogued as COSV61017743; called by muse, mutect2, varscan2
- ACAN | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 201/419 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61370741; called by muse, mutect2, varscan2
- ACCS | c.555G>A p.G185= | Splice Region (SNP) | VAF 183/387 reads (47%) | catalogued as rs988555326; called by muse, mutect2, varscan2
- ACE | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 236/521 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs147670020; called by muse, mutect2, varscan2
- ADAM2 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 168/268 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV99696937; called by muse, mutect2, varscan2
- ADCY9 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 160/351 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV53576157; called by muse, mutect2, varscan2
- ADH1C | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 146/382 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs753685476; called by muse, mutect2, varscan2
- AJAP1 | c.1164-1G>A p.X388_splice | Splice Site (SNP) | VAF 112/121 reads (93%) | catalogued as COSV65454010; called by muse, mutect2, varscan2
- ALS2 | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 188/409 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1437975145; called by muse, mutect2, varscan2
- ANKRD30B | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV62821470; called by muse, mutect2, varscan2
- ANKRD50 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 202/447 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72385750; called by muse, mutect2, varscan2
- APH1A | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.245); catalogued as rs782134229; called by muse, mutect2, varscan2
- APOB | c.8822C>T p.T2941I | Missense Mutation (SNP) | VAF 229/473 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs768600483, COSV51936981, COSV99263491; called by muse, mutect2, varscan2
- APOH | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779872282; called by muse, mutect2, varscan2
- ARID1B | c.4462G>A p.V1488I | Missense Mutation (SNP) | VAF 275/640 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.071); catalogued as rs768210321, COSV99268671; called by muse, mutect2, varscan2
- ASPM | c.8050G>A p.D2684N | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV54129185; called by muse, mutect2, varscan2
- ATF7IP | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 124/257 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs763268952; called by muse, mutect2, varscan2
- ATM | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1445292591; called by muse, mutect2, varscan2
- ATM | c.3905G>A p.G1302D | Missense Mutation (SNP) | VAF 186/419 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as CD982455; called by muse, mutect2, varscan2
- BAHCC1 | c.5036G>A p.G1679E | Missense Mutation (SNP) | VAF 299/574 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1555657604; called by muse, mutect2, varscan2
- BICD1 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 152/337 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV55676666; called by muse, mutect2, varscan2
- BOD1L1 | c.5122G>A p.D1708N | Missense Mutation (SNP) | VAF 196/408 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV50010674; called by muse, mutect2, varscan2
- BRCA2 | c.4426G>A p.D1476N | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.857); catalogued as rs1380537823, COSV66456191; called by muse, mutect2, varscan2
- BST1 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 120/292 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs773717822; called by muse, mutect2, varscan2
- BTBD8 | c.1769C>T p.S590L (on ENST00000636805 / NM_001376131.1; = p.S77L on NM_015237.4) | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs1195453133, COSV64885551; called by muse, mutect2, varscan2
- C2CD2L | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1272428368; called by muse, mutect2, varscan2
- C2CD3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 148/334 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100487359; called by muse, mutect2, varscan2
- CABIN1 | c.5827G>A p.V1943M | Missense Mutation (SNP) | VAF 356/1033 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.365); catalogued as rs1300181578; called by muse, mutect2, varscan2
- CACNA1H | c.5665G>A p.G1889R | Missense Mutation (SNP) | VAF 367/754 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs201018826; called by muse, mutect2, varscan2
- CACNA2D1 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 69/294 reads (23%) | catalogued as rs1554385501, COSV100666950; called by muse, mutect2, varscan2
- CARMIL3 | c.3995C>T p.P1332L | Missense Mutation (SNP) | VAF 266/543 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.087); catalogued as rs1463197899; called by muse, mutect2, varscan2
- CASZ1 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 44/789 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs747304331, COSV65455655; called by muse, mutect2
- CATSPERD | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 81/256 reads (32%) | catalogued as rs1478424485; called by muse, mutect2, varscan2
- CBX3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 182/888 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as COSV61761441; called by muse, mutect2, varscan2
- CCDC174 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 14/334 reads (4%) | catalogued as rs1432406778, COSV100358735, COSV57979810; called by muse, mutect2
- CCDC60 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 127/283 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59547479; called by muse, mutect2, varscan2
- CCDC88C | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 168/342 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753634468; called by muse, mutect2, varscan2
- CCDC88C | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 255/483 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs371147165; called by muse, mutect2, varscan2
- CCNE1 | c.1196G>A p.S399N | Missense Mutation (SNP) | VAF 249/860 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52904541; called by muse, mutect2, varscan2
- CDC45 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 115/341 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99597181; called by muse, mutect2, varscan2
- CDON | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.424); catalogued as COSV99701884; called by muse, mutect2, varscan2
- CEACAM5 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 216/746 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs782660405; called by muse, varscan2
- CEACAM8 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 128/371 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as rs377727534; called by muse, mutect2, varscan2
- CHGB | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 207/644 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs771393741, COSV66759682, COSV66761431; called by muse, mutect2, varscan2
- CHRNA4 | c.1652C>T p.T551I | Missense Mutation (SNP) | VAF 372/1814 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as rs79438238; called by muse, mutect2
- CHSY3 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 144/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1227807356; called by muse, mutect2, varscan2
- CNTNAP5 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 270/597 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as rs763503706, COSV70483831; called by muse, mutect2, varscan2
- COL18A1 | c.2417C>T p.P806L (on ENST00000359759 / NM_130444.3; = p.P571L on NM_030582.4) | Missense Mutation (SNP) | VAF 319/700 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); catalogued as rs1333056556, COSV62701076; called by muse, mutect2, varscan2
- COL6A3 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 194/449 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs865791056, COSV55084377; called by muse, mutect2, varscan2
- CPS1 | c.3953T>A p.L1318* | Nonsense Mutation (SNP) | VAF 128/268 reads (48%) | catalogued as CM120166; called by muse, mutect2, varscan2
- CROCC | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 686/1482 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs762565818, COSV65011398; called by muse, varscan2
- CSMD1 | c.8849G>A p.G2950E (on ENST00000520002; = p.G2949E on NM_033225.6) | Missense Mutation (SNP) | VAF 233/484 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59372856; called by muse, mutect2, varscan2
- CTAGE6 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 137/869 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV101417803; called by muse, mutect2, varscan2
- CTR9 | c.692G>A p.C231Y | Missense Mutation (SNP) | VAF 168/419 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV63728642; called by muse, mutect2, varscan2
- DAO | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 164/393 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323058; called by muse, mutect2, varscan2
- DCC | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 240/470 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV71427379, COSV71437043; called by muse, mutect2, varscan2
- DCDC1 | c.3284G>A p.S1095N (on ENST00000597505 / NM_001367979.1; = p.S202N on NM_020869.3) | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV100338503; called by muse, mutect2, varscan2
- DCHS1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 233/521 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413559157; called by muse, mutect2, varscan2
- DDX10 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as COSV59433393; called by muse, mutect2, varscan2
- DDX60L | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 177/406 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.163); catalogued as COSV52720980; called by muse, mutect2, varscan2
- DENND3 | c.957G>A p.R319= | Splice Region (SNP) | VAF 174/350 reads (50%) | catalogued as rs1555546497; called by muse, mutect2, varscan2
- DENND4C | c.3922G>A p.E1308K (on ENST00000434457 / NM_001330640.2; = p.E1259K on NM_017925.7) | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as rs745779880; called by muse, mutect2, varscan2
- DGKI | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 130/448 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55956257; called by muse, mutect2, varscan2
- DHX34 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 346/1002 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60895165; called by muse, mutect2, varscan2
- DNAH11 | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 143/464 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs563280837, COSV60956774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV52339016, COSV52345524; called by muse, mutect2, varscan2
- DNAJA4 | c.896G>A p.G299E (on ENST00000343789; = p.G328E on NM_018602.3) | Missense Mutation (SNP) | VAF 182/372 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV51217815, COSV99144553; called by muse, mutect2, varscan2
- DOCK5 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 190/317 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99376487; called by muse, mutect2, varscan2
- DSCAM | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 144/319 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as rs1252993421; called by muse, mutect2, varscan2
- DSG3 | c.2566C>T p.L856F | Missense Mutation (SNP) | VAF 163/315 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771266691; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 247/500 reads (49%) | catalogued as rs770745137; called by muse, mutect2, varscan2
- EFCAB8 | c.2926G>A p.V976I | Missense Mutation (SNP) | VAF 154/540 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.38); catalogued as rs1378666516, COSV62498721; called by muse, mutect2
- EIF2S3B | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 165/381 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs757969315, COSV59372816; called by muse, mutect2, varscan2
- ENO1 | c.865+1G>A p.X289_splice | Splice Site (SNP) | VAF 142/256 reads (55%) | catalogued as rs759857368; called by muse, mutect2, varscan2
- EPB41L3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 228/488 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59450932; called by muse, mutect2, varscan2
- EPHA5 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56637602; called by muse, mutect2, varscan2
- EPHB2 | c.2122G>A p.D708N (on ENST00000400191 / NM_001309193.2; = p.D709N on NM_004442.7) | Missense Mutation (SNP) | VAF 152/409 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101006881; called by muse, mutect2, varscan2
- EPN1 | c.955G>A p.D319N (on ENST00000270460 / NM_001321263.1; = p.D294N on NM_013333.3) | Missense Mutation (SNP) | VAF 422/1330 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs767673424; called by muse, mutect2, varscan2
- EVC2 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs773470850; called by muse, mutect2, varscan2
- F5 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 170/403 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV63122792; called by muse, mutect2, varscan2
- FAM181B | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 342/708 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as rs1233338330; called by muse, mutect2, varscan2
- FAM193A | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 223/466 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.943); catalogued as rs530360787; called by muse, mutect2, varscan2
- FASTKD3 | c.1919G>A p.R640K | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs760818288; called by muse, mutect2, varscan2
- FBF1 | c.2020G>A p.A674T (on ENST00000586717; = p.A688T on NM_001319193.1) | Missense Mutation (SNP) | VAF 288/606 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs1398559938; called by muse, mutect2, varscan2
- FER | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99811182; called by muse, mutect2, varscan2
- FHL5 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100459500; called by muse, mutect2, varscan2
- FIBCD1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 262/581 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1052381227; called by muse, mutect2, varscan2
- FLNB | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 163/334 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55876013; called by muse, mutect2, varscan2
- FOS | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 262/523 reads (50%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.968); catalogued as rs1446975713; called by muse, mutect2, varscan2
- FOXB1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 201/412 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456464426, COSV101249685; called by muse, mutect2, varscan2
- FSIP2 | c.3669G>A p.W1223* | Nonsense Mutation (SNP) | VAF 153/314 reads (49%) | catalogued as COSV58101546; called by muse, mutect2, varscan2
- GAP43 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 251/571 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as COSV59348714; called by muse, mutect2, varscan2
- GATAD2B | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 168/387 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs752198126; called by muse, mutect2, varscan2
- GHRHR | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV58198186; called by muse, mutect2, varscan2
- GIPR | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 192/672 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1298512253, COSV54424108; called by muse, mutect2, varscan2
- GJA9 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 124/634 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100668111; called by muse, mutect2, varscan2
- GLB1L3 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.216); catalogued as COSV66280578; called by muse, mutect2, varscan2
- GLIS1 | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 326/703 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1005201769; called by muse, mutect2, varscan2
- GPR137C | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 153/362 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs768360524; called by muse, mutect2, varscan2
- GPR142 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 283/587 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as rs756897767; called by muse, mutect2, varscan2
- GRB2 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 154/357 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1430561495; called by muse, mutect2, varscan2
- GRIK2 | c.1724G>A p.S575N | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59769951; called by muse, mutect2, varscan2
- GRM3 | c.2036G>T p.R679M | Missense Mutation (SNP) | VAF 154/559 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64468213; called by muse, mutect2, varscan2
- GRM5 | c.2917G>A p.G973S (on ENST00000305447 / NM_001143831.2; = p.G941S on NM_000842.4) | Missense Mutation (SNP) | VAF 444/858 reads (52%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.02); catalogued as rs200967678; called by muse, mutect2, varscan2
- HACL1 | c.1481G>A p.W494* | Nonsense Mutation (SNP) | VAF 70/236 reads (30%) | catalogued as rs1168342042; called by muse, mutect2, varscan2
- HELZ | c.3499C>T p.P1167S | Missense Mutation (SNP) | VAF 142/530 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as rs183613778, COSV62377316; called by muse, mutect2, varscan2
- HMCN1 | c.4801C>T p.Q1601* | Nonsense Mutation (SNP) | VAF 231/536 reads (43%) | catalogued as COSV54901557; called by muse, mutect2, varscan2
- HNF4A | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 223/705 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM133276; called by muse, mutect2, varscan2
- HNRNPA1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 135/336 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV52937943; called by muse, varscan2
- HNRNPDL | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 120/237 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1235371971; called by muse, mutect2, varscan2
- HOMEZ | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 261/538 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100664209; called by muse, mutect2, varscan2
- HOXA9 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 268/939 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58655788; called by muse, mutect2, varscan2
- HSPA13 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 161/396 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341963321; called by muse, mutect2, varscan2
- IHO1 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | catalogued as rs1477749140, COSV56507696; called by muse, mutect2, varscan2
- ILDR2 | c.1211+1G>A p.X404_splice | Splice Site (SNP) | VAF 112/226 reads (50%) | catalogued as COSV54836076; called by muse, varscan2
- INAFM1 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 249/822 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1322045680; called by muse, mutect2, varscan2
- IP6K1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs764431758; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.292-1G>A p.X98_splice (on ENST00000485419 / NM_001197113.1; = p.X22_splice on NM_014575.3) | Splice Site (SNP) | VAF 200/381 reads (52%) | catalogued as rs1309293788; called by muse, mutect2, varscan2
- JCAD | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV64758055; called by muse, mutect2, varscan2
- JSRP1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 322/987 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV99677786; called by muse, mutect2, varscan2
- KASH5 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 221/777 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs761859737; called by muse, mutect2, varscan2
- KCNH1 | c.2392G>A p.V798I (on ENST00000271751 / NM_172362.3; = p.V771I on NM_002238.4) | Missense Mutation (SNP) | VAF 53/784 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs761754626, COSV55085456; called by muse, mutect2
- KCNQ2 | c.2194C>T p.P732S (on ENST00000359125 / NM_172107.4; = p.P704S on NM_004518.6) | Missense Mutation (SNP) | VAF 554/2286 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs749597397; called by muse, mutect2, varscan2
- KDM3A | c.2932G>A p.V978M | Missense Mutation (SNP) | VAF 98/178 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1458921571; called by muse, mutect2, varscan2
- KDM5D | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 319/689 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100522190; called by muse, mutect2, varscan2
- KIAA1549 | c.3988G>A p.D1330N | Missense Mutation (SNP) | VAF 214/743 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs533057424; called by muse, mutect2, varscan2
- KIF19 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 423/816 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs775255824; called by muse, mutect2, varscan2
- KIF24 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934573071, COSV61454777; called by muse, mutect2, varscan2
- KLF9 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 105/190 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772506798, COSV101009616; called by muse, mutect2, varscan2
- KMT2C | c.5167G>A p.D1723N | Missense Mutation (SNP) | VAF 205/656 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs200338679; called by muse, mutect2, varscan2
- KRT15 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 276/617 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.072); catalogued as rs555279126; called by muse, mutect2, varscan2
- KRTAP10-9 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 242/545 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59966798; called by muse, mutect2, varscan2
- LILRB5 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 266/1037 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100300748; called by muse, mutect2, varscan2
- LMO7 | c.2344G>A p.V782I (on ENST00000357063; = p.V463I on NM_005358.5) | Missense Mutation (SNP) | VAF 99/100 reads (99%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1399921006, COSV58552359; called by muse, mutect2, varscan2
- LPA | c.3794C>T p.T1265M | Missense Mutation (SNP) | VAF 110/223 reads (49%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs752058838; called by muse, mutect2, varscan2
- LRCH4 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 375/1246 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.091); catalogued as rs1416011438; called by muse, mutect2, varscan2
- LRRC14B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 302/639 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs552867607; called by muse, mutect2, varscan2
- LRRC2 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 115/299 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs776257045; called by muse, mutect2, varscan2
- LTBP2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 429/857 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.058); catalogued as rs553562104, COSV56213477; called by muse, mutect2, varscan2
- LY75 | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 143/330 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs1308176006; called by muse, mutect2, varscan2
- LZTS3 | c.1301G>A p.R434Q (on ENST00000329152; = p.R388Q on NM_001282533.2) | Missense Mutation (SNP) | VAF 246/776 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs1332163331, COSV100232085, COSV61278145; called by muse, mutect2, varscan2
- MAML1 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 242/510 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99483591; called by muse, varscan2
- MAN2A1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 148/342 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54851612; called by muse, mutect2, varscan2
- MAP1S | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 422/1198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418134241; called by muse, mutect2, varscan2
- MARK1 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV65067232; called by muse, mutect2, varscan2
- MC3R | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 199/590 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99710806; called by muse, mutect2, varscan2
- MCC | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 242/494 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs748327549; called by muse, mutect2, varscan2
- METTL14 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66310759; called by muse, mutect2, varscan2
- METTL26 | c.488+1G>A p.X163_splice | Splice Site (SNP) | VAF 215/475 reads (45%) | catalogued as rs199799134; called by muse, mutect2, varscan2
- MINDY4 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54672992; called by muse, mutect2, varscan2
- MKRN3 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 292/668 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs1487520973, COSV58811273; called by muse, mutect2, varscan2
- MLLT1 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 272/1025 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53132483; called by muse, mutect2, varscan2
- MMP15 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 192/439 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs745919855; called by muse, mutect2, varscan2
- MORC1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 116/259 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99226086; called by muse, mutect2, varscan2
- MS4A14 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1378929378; called by muse, mutect2, varscan2
- MUC16 | c.19567C>T p.P6523S | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV67501710; called by muse, mutect2, varscan2
- MUC16 | c.18697C>T p.P6233S | Missense Mutation (SNP) | VAF 203/579 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs376365857; called by muse, mutect2, varscan2
- MUC16 | c.13430C>T p.S4477F | Missense Mutation (SNP) | VAF 202/677 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs1353871237; called by muse, mutect2, varscan2
- MUC16 | c.12833C>T p.S4278F | Missense Mutation (SNP) | VAF 152/538 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs1323347445, COSV67469508; called by muse, varscan2
- MXRA5 | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV99476118; called by muse, mutect2, varscan2
- NBAS | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs1250190572; called by muse, mutect2, varscan2
- NCOA7 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs768462504; called by muse, mutect2, varscan2
- NDUFA13 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 183/604 reads (30%) | catalogued as COSV99389202; called by muse, mutect2, varscan2
- NDUFV2 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 106/216 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs770259847, COSV100571730; called by muse, mutect2, varscan2
- NEK11 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 125/298 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1280450371; called by muse, mutect2, varscan2
- NFE2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 130/268 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV56456438; called by muse, mutect2, varscan2
- NIPBL | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 247/522 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV99241184; called by muse, mutect2, varscan2
- NPIPB5 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 120/796 reads (15%) | SIFT tolerated, low confidence (0.09); catalogued as rs750310002; called by muse, varscan2
- NR4A3 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 28/621 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs960550123, COSV58249009; called by muse, mutect2
- NRP1 | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99588258; called by muse, mutect2, varscan2
- NT5DC2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58733833; called by muse, mutect2, varscan2
- NTNG1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 229/496 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99639882; called by muse, mutect2, varscan2
- NUP98 | c.3499G>A p.E1167K (on ENST00000359171 / NM_001365126.1; = p.E1150K on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 188/487 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.397); catalogued as rs775968781; called by muse, mutect2, varscan2
- OLR1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 178/366 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs753070166; called by muse, mutect2, varscan2
- OR2M5 | c.569A>T p.N190I | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV63547196; called by muse, mutect2, varscan2
- OR3A1 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 240/579 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs372102685; called by muse, mutect2
- OR4D10 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 165/396 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs764383479; called by muse, mutect2, varscan2
- OR4M1 | c.352A>G p.M118V | Missense Mutation (SNP) | VAF 160/280 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100270967; called by muse, varscan2
- OR52D1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 221/485 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781665830; called by muse, mutect2, varscan2
- OR5B17 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62160827; called by muse, mutect2, varscan2
- OR5B2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 106/227 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs369296397; called by muse, mutect2, varscan2
- OR7A10 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 135/456 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764338523, COSV50166447; called by muse, mutect2, varscan2
- OR8B12 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 255/500 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1336257012; called by muse, mutect2, varscan2
- PABPC1L | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 149/515 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99407931; called by muse, mutect2, varscan2
- PADI1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 220/676 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64937988; called by muse, mutect2, varscan2
- PADI3 | c.1904C>T p.T635I | Missense Mutation (SNP) | VAF 385/660 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.122); catalogued as rs767108956; called by muse, mutect2, varscan2
- PAM | c.2720G>A p.G907E (on ENST00000438793 / NM_001319943.1; = p.G908E on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/255 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs543056414; called by muse, mutect2, varscan2
- PATJ | c.4247G>A p.G1416D | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56247974; called by muse, mutect2, varscan2
- PAX4 | c.645+1G>A p.X215_splice | Splice Site (SNP) | VAF 177/582 reads (30%) | catalogued as COSV100490191; called by muse, mutect2, varscan2
- PCBP2 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 91/177 reads (51%) | catalogued as COSV100827422, COSV63729265; called by muse, mutect2, varscan2
- PDE10A | c.2286G>A p.W762* | Nonsense Mutation (SNP) | VAF 121/281 reads (43%) | catalogued as COSV63092303, COSV63098680; called by muse, mutect2, varscan2
- PDE4D | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 408/789 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1480373658; called by muse, mutect2, varscan2
- PDE6B | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 193/420 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs373925141; called by muse, mutect2, varscan2
- PECR | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54734593; called by muse, varscan2
- PGM5 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 158/742 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.875); catalogued as rs782483282; called by muse, mutect2, varscan2
- PHF19 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 315/624 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs200127495, COSV56489651; called by muse, mutect2, varscan2
- PHIP | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 137/288 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51503561; called by muse, mutect2, varscan2
- PIBF1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58319746; called by muse, mutect2, varscan2
- PLA2G4F | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 166/418 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs143229349; called by muse, mutect2, varscan2
- PLEKHM2 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 344/1332 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.092); catalogued as rs751121316; called by muse, mutect2, varscan2
- PLOD2 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 133/280 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV51461966; called by muse, mutect2, varscan2
- PLS1 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 159/338 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61832936; called by muse, mutect2, varscan2
- PNPLA7 | c.2144C>T p.T715M | Missense Mutation (SNP) | VAF 305/618 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1192704454, COSV52999448; called by muse, mutect2, varscan2
- PPP1R9A | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 166/593 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195714; called by muse, mutect2, varscan2
- PRAMEF17 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 75/189 reads (40%) | catalogued as COSV65816231; called by muse, mutect2, varscan2
- PRKG2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 231/452 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52319078; called by muse, mutect2, varscan2
- PSMC2 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53006678; called by muse, mutect2, varscan2
- PTGES3 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV56273548; called by muse, mutect2, varscan2
- RAI1 | c.3119G>A p.G1040E | Missense Mutation (SNP) | VAF 323/712 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.84); catalogued as rs775150135; called by muse, mutect2, varscan2
- RAI1 | c.3218G>A p.G1073D | Missense Mutation (SNP) | VAF 357/760 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as rs1419475241; called by muse, mutect2, varscan2
- RAX | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 327/681 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1178316569; called by muse, mutect2, varscan2
- RBM34 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs370629801; called by muse, mutect2, varscan2
- RC3H2 | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.785); catalogued as rs200582531; called by muse, mutect2, varscan2
- RDH12 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 83/200 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs754373553; called by muse, mutect2, varscan2
- RHOQ | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 114/116 reads (98%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53190153, COSV99475865; called by muse, mutect2, varscan2
- RINL | c.857C>T p.A286V (on ENST00000591812 / NM_001195833.2; = p.A172V on NM_198445.4) | Missense Mutation (SNP) | VAF 280/976 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs201138591; called by muse, mutect2, varscan2
- RNF123 | c.2311G>A p.G771S | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.769); catalogued as rs868494915; called by muse, mutect2, varscan2
- ROBO4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 255/565 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as rs762765651, COSV60621735; called by muse, mutect2, varscan2
- RPIA | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 234/512 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52171757, COSV99376570; called by muse, mutect2, varscan2
- RSAD2 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 164/378 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV101150022; called by muse, varscan2
- SACS | c.11375G>A p.R3792Q | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.799); catalogued as rs778633704; called by muse, mutect2, varscan2
- SAG | c.513G>A p.K171= | Splice Region (SNP) | VAF 153/154 reads (99%) | catalogued as COSV68590773; called by muse, mutect2, varscan2
- SAMD9 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 159/601 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.355); catalogued as rs775712957; called by muse, mutect2, varscan2
- SCAF1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 185/692 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs761751484; called by muse, mutect2, varscan2
- SDK1 | c.5599C>T p.R1867W | Missense Mutation (SNP) | VAF 288/767 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142107345; called by muse, mutect2, varscan2
- SEC14L1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 143/299 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66725796; called by muse, mutect2, varscan2
- SELENOO | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 157/158 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1318849054; called by muse, mutect2, varscan2
- SERPINC1 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 192/420 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113675; called by muse, mutect2, varscan2
- SFRP4 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 189/673 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV71412370; called by muse, mutect2, varscan2
- SGPP2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 136/258 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138702204, COSV58330549; called by muse, mutect2, varscan2
- SGPP2 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 190/419 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs1192472260; called by muse, mutect2, varscan2
- SIGLEC12 | c.959C>T p.T320I (on ENST00000291707 / NM_053003.4; = p.T202I on NM_033329.2) | Missense Mutation (SNP) | VAF 237/866 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); catalogued as rs769143281; called by muse, mutect2, varscan2
- SIGLEC6 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 249/794 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1158191358; called by muse, mutect2, varscan2
- SLA2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 202/721 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs200208007; called by muse, mutect2, varscan2
- SLC16A14 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 312/679 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99725857; called by muse, mutect2, varscan2
- SLC17A7 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 167/555 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55550614; called by muse, mutect2, varscan2
- SLC22A14 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 282/512 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99828291; called by muse, mutect2, varscan2
- SLC2A10 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 256/836 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763372108; called by muse, varscan2
- SLC3A1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs199678349; called by muse, mutect2, varscan2
- SLC47A1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs1176534699, COSV99565405; called by muse, mutect2, varscan2
- SLC4A5 | c.1025+1G>A p.X342_splice | Splice Site (SNP) | VAF 155/319 reads (49%) | catalogued as rs1558880876; called by muse, mutect2, varscan2
- SLC6A20 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 194/424 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs775225439, COSV62071062; called by muse, mutect2, varscan2
- SLFN12 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 125/309 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs764941956, COSV59226778; called by muse, mutect2, varscan2
- SLMAP | c.1321G>A p.V441M (on ENST00000428312 / NM_001377924.1; = p.V462M on NM_007159.5) | Missense Mutation (SNP) | VAF 164/356 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as rs1368014490; called by muse, mutect2, varscan2
- SNED1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 288/625 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs958567301; called by muse, mutect2, varscan2
- SNRPA | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 215/760 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs1158032963; called by muse, mutect2, varscan2
- SOCS2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 125/274 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292602320; called by muse, mutect2, varscan2
- SPEF2 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61551974; called by muse, mutect2, varscan2
- SPPL2A | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs781566248; called by muse, mutect2, varscan2
- SPRED3 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 286/1014 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1490646399; called by muse, mutect2, varscan2
- SPTA1 | c.5692G>A p.E1898K | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63758463, COSV63762100; called by muse, mutect2, varscan2
- SSBP1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 150/545 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV99519850; called by muse, mutect2, varscan2
- STK3 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 153/290 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1563702776; called by muse, mutect2, varscan2
- SUGCT | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751540603, COSV59330454; called by muse, mutect2, varscan2
- SV2A | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 251/546 reads (46%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.018); catalogued as rs782641312; called by muse, mutect2, varscan2
- SVEP1 | c.6988G>A p.E2330K | Missense Mutation (SNP) | VAF 176/377 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754419975; called by muse, mutect2, varscan2
- SYCP1 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1427841221; called by muse, mutect2, varscan2
- SYNE2 | c.10016del p.K3339Rfs*5 | Frame Shift Del (DEL) | VAF 157/395 reads (40%) | catalogued as COSV59974984; called by mutect2, pindel, varscan2
- SYT17 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 88/164 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs1475095681; called by muse, mutect2, varscan2
- TBL3 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 395/880 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as rs1054597441; called by muse, mutect2
- TDO2 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs762745653; called by muse, mutect2, varscan2
- TF | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 282/591 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as COSV99396527; called by muse, mutect2, varscan2
- THAP12 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 193/395 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.383); catalogued as rs989114523, COSV52612663; called by muse, mutect2, varscan2
- TIAM1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 261/501 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54537099; called by muse, mutect2, varscan2
- TIAM2 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 206/400 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562328671; called by muse, mutect2, varscan2
- TMEM126B | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs139974357; called by muse, mutect2, varscan2
- TMEM132C | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 298/663 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100175058; called by muse, mutect2, varscan2
- TMEM132D | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 220/451 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67163019; called by muse, mutect2, varscan2
- TMEM170B | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 151/329 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101053260; called by muse, mutect2, varscan2
- TMEM207 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 178/411 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1414625440; called by muse, mutect2, varscan2
- TMEM71 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 107/221 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs551754127, COSV63457486, COSV63459280; called by muse, mutect2, varscan2
- TMEM87B | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1221567422; called by muse, mutect2, varscan2
- TNN | c.3590C>T p.T1197M | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750138050; called by muse, varscan2
- TP53BP1 | c.3800G>A p.R1267K | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55511722; called by muse, mutect2, varscan2
- TPX2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 139/510 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs775408777; called by muse, mutect2, varscan2
- TPX2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 126/433 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV100301690; called by muse, mutect2, varscan2
- TRANK1 | c.2882G>A p.G961D | Missense Mutation (SNP) | VAF 198/425 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV57143181; called by muse, mutect2, varscan2
- TRAPPC9 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 183/537 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV66909558; called by muse, mutect2, varscan2
- TRIM58 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 143/320 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1380221051; called by muse, mutect2, varscan2
- TRIO | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.223); catalogued as rs1031853907; called by muse, mutect2, varscan2
- TTBK1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 209/501 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs370022725, COSV52488871, COSV52492583; called by muse, mutect2, varscan2
- TTN | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 196/409 reads (48%) | PolyPhen probably damaging (0.996); catalogued as rs747867752, COSV59862739; called by muse, mutect2, varscan2
- TUBG1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 215/645 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs1203383045; called by muse, mutect2, varscan2
- TXNDC5 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 232/503 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1331817479; called by muse, mutect2, varscan2
- UBR2 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65751946; called by muse, mutect2, varscan2
- UGT2A1 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 172/367 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763710867; called by muse, mutect2, varscan2
- UNC13D | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 204/415 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs962992811; called by muse, mutect2, varscan2
- UNC5C | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 145/341 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs200667278; called by muse, mutect2, varscan2
- USH1C | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 124/345 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs267602805, COSV50014069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP44 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 120/300 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51562781; called by muse, mutect2, varscan2
- USP6 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 143/315 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs1567787859; called by muse, mutect2, varscan2
- VPS28 | c.39C>T p.A13= | Splice Region (SNP) | VAF 156/342 reads (46%) | catalogued as rs1257554712, COSV99034920; called by muse, mutect2, varscan2
- WDR75 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 149/325 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1336635084; called by muse, mutect2, varscan2
- XIRP2 | c.7141G>A p.E2381K (on ENST00000628543; = p.E2556K on NM_152381.6) | Missense Mutation (SNP) | VAF 148/341 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs145874680, COSV54701233, COSV54707403; called by muse, mutect2, varscan2
- ZBTB1 | c.1996G>A p.V666I | Missense Mutation (SNP) | VAF 177/372 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs1387954698; called by muse, mutect2, varscan2
- ZBTB10 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 287/642 reads (45%) | catalogued as COSV66946738; called by muse, mutect2, varscan2
- ZEB2 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 120/240 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV57951239; called by muse, mutect2, varscan2
- ZFP30 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 113/409 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as COSV63623015; called by muse, mutect2, varscan2
- ZNF521 | c.3929G>A p.S1310N | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.258); catalogued as rs1426103422; called by mutect2, varscan2
- ZNF560 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 113/435 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV56872547; called by muse, mutect2, varscan2
- ZNF92 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.4); catalogued as COSV60872950; called by muse, mutect2, varscan2
- ZSWIM6 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 224/446 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs747444881; called by muse, mutect2, varscan2
- AACS | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 161/306 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- ABCB5 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 186/589 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ABCB9 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 263/591 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ABHD17A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 306/1048 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ACE | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ADAM29 | c.1078A>G p.N360D | Missense Mutation (SNP) | VAF 205/432 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ADAMTS6 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 152/378 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ADCY3 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 271/506 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ADCY4 | c.2783G>A p.G928D | Missense Mutation (SNP) | VAF 135/323 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADGB | c.3074C>T p.T1025I | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ADGRB3 | c.3349G>A p.V1117I | Missense Mutation (SNP) | VAF 192/470 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ADGRD1 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 151/305 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ADGRV1 | c.2687G>A p.G896D | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADM | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 329/665 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADRB3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 171/504 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- AGBL2 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AGBL5 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 138/302 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- AGGF1 | c.1634-1G>A p.X545_splice | Splice Site (SNP) | VAF 83/180 reads (46%) | called by muse, mutect2, varscan2
- AHDC1 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 458/929 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.125); called by muse, mutect2
- AIFM3 | c.465G>A p.Q155= | Splice Region (SNP) | VAF 225/468 reads (48%) | called by muse, mutect2, varscan2
- ALCAM | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 196/438 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOX15B | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 189/383 reads (49%) | called by muse, mutect2, varscan2
- ANAPC7 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 210/447 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ANKRD36 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- ARAP1 | c.3532G>A p.V1178M (on ENST00000393609 / NM_001040118.2; = p.V933M on NM_015242.4) | Missense Mutation (SNP) | VAF 147/343 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ARF5 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 102/417 reads (24%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 143/518 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP44 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 150/331 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ATG2B | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BBC3 | c.371C>A p.P124H (on ENST00000449228 / NM_001127240.3; = p.P90T on NM_014417.5) | Missense Mutation (SNP) | VAF 213/646 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- BICRA | c.4480G>A p.D1494N | Missense Mutation (SNP) | VAF 355/1262 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMF | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 200/418 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPTF | c.5383G>A p.G1795R | Missense Mutation (SNP) | VAF 206/424 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- BRMS1L | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- BRPF3 | c.2765G>A p.G922D | Missense Mutation (SNP) | VAF 192/469 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- BTBD3 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 218/708 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- BUD13 | c.272T>A p.V91E | Missense Mutation (SNP) | VAF 156/550 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- C16orf95 | c.464C>T p.P155L (on ENST00000253461 / NM_001195125.2; = p.P216= on NM_001195124.3) | Missense Mutation (SNP) | VAF 268/573 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- C20orf173 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 274/876 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- C2CD4C | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 498/1333 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- C5orf22 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- CAMSAP1 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 131/294 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CAMSAP2 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 155/330 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAMSAP3 | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 204/633 reads (32%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.3221C>T p.S1074F | Missense Mutation (SNP) | VAF 231/721 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CANX | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 96/185 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CATSPER3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 121/270 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CBX8 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 155/344 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC151 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 278/897 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CCDC177 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 280/604 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC88B | c.2952G>C p.E984D | Missense Mutation (SNP) | VAF 183/429 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CCNB2 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCZ1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CD300LB | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 159/370 reads (43%) | called by muse, mutect2, varscan2
- CDCA7 | c.346G>A p.E116K (on ENST00000347703 / NM_145810.3; = p.E195K on NM_031942.5) | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CDCP1 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 152/344 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CDHR3 | c.1482C>A p.S494R | Missense Mutation (SNP) | VAF 190/861 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEACAM3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 105/312 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR3 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 372/767 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP290 | c.2991+1G>A p.X997_splice | Splice Site (SNP) | VAF 68/143 reads (48%) | called by muse, mutect2, varscan2
- CEP43 | c.103-1G>A p.X35_splice | Splice Site (SNP) | VAF 147/312 reads (47%) | called by muse, mutect2, varscan2
- CEP68 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 226/461 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CFAP43 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAF1A | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 324/969 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CIT | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 194/390 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- CLCNKA | c.577-1G>A p.X193_splice | Splice Site (SNP) | VAF 224/926 reads (24%) | called by muse, mutect2, varscan2
- CLEC9A | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 182/418 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLIC6 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 306/663 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLNK | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CLTCL1 | c.3562G>A p.D1188N | Missense Mutation (SNP) | VAF 189/428 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- CMIP | c.2122G>A p.E708K (on ENST00000537098 / NM_198390.2; = p.E614K on NM_030629.3) | Missense Mutation (SNP) | VAF 214/456 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- CMTR1 | c.1821G>A p.G607= | Splice Region (SNP) | VAF 133/261 reads (51%) | called by muse, mutect2, varscan2
- CNTN6 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 131/243 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COBLL1 | c.230C>T p.S77F (on ENST00000392717; = p.S39F on NM_014900.5) | Missense Mutation (SNP) | VAF 223/487 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- COL15A1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 264/608 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL2A1 | c.2294G>A p.G765D | Missense Mutation (SNP) | VAF 175/335 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A3 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 139/334 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CPHXL | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 166/387 reads (43%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CPSF6 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 247/530 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CTAGE8 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 84/618 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CTNNBL1 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 100/413 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CTRB2 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DAAM2 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 207/441 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DACT1 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 293/606 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DCAF8 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DDX52 | c.859+1G>A p.X287_splice | Splice Site (SNP) | VAF 104/255 reads (41%) | called by muse, mutect2, varscan2
- DDX60 | c.3443C>T p.T1148I | Missense Mutation (SNP) | VAF 138/325 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DENND2C | c.1387G>A p.A463T (on ENST00000393274 / NM_001256404.2; = p.A406T on NM_198459.4) | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DEPDC5 | c.2720G>A p.G907D (on ENST00000400246; = p.G976D on NM_014662.5) | Missense Mutation (SNP) | VAF 308/597 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DIAPH3 | c.2290C>T p.Q764* (on ENST00000400324 / NM_001042517.2; = p.Q501* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 122/122 reads (100%) | called by muse, mutect2, varscan2
- DIP2B | c.3148G>A p.V1050M | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DMPK | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 275/1000 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH14 | c.9232C>T p.H3078Y (on ENST00000445597; = p.H4086Y on NM_001367479.1) | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.11818G>A p.D3940N | Missense Mutation (SNP) | VAF 129/263 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DOCK4 | c.4846C>T p.P1616S | Missense Mutation (SNP) | VAF 127/463 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DOK3 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 404/849 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOP1B | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 155/366 reads (42%) | SIFT tolerated (0.81); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DPYS | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 234/498 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DRD2 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 324/732 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- DSC2 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- DSCAML1 | c.6233C>T p.T2078I (on ENST00000321322; = p.T2018I on NM_020693.4) | Missense Mutation (SNP) | VAF 200/467 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- DSG1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DST | c.1986+1G>A p.X662_splice (on ENST00000361203 / NM_001374722.1; = p.X336_splice on NM_001723.6) | Splice Site (SNP) | VAF 78/146 reads (53%) | called by muse, mutect2, varscan2
- DTNA | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 193/426 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DYNC2LI1 | c.126G>A p.G42= | Splice Region (SNP) | VAF 130/130 reads (100%) | called by muse, mutect2, varscan2
- E2F3 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 175/382 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ECM2 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EFCAB14 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 209/436 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- EFNB2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 325/325 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- EGR4 | c.1127del p.P376Rfs*4 (on ENST00000545030; = p.P273Rfs*4 on NM_001965.4) | Frame Shift Del (DEL) | VAF 309/795 reads (39%) | called by mutect2, pindel, varscan2
- EGR4 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 498/1002 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EHBP1L1 | c.3970C>T p.P1324S | Missense Mutation (SNP) | VAF 301/653 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- EHMT1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 222/506 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF3H | c.684_686del p.H228_E229delinsQ | In Frame Del (DEL) | VAF 129/333 reads (39%) | called by mutect2, pindel, varscan2
- EML5 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- EML6 | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 158/375 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ENTR1 | c.848G>A p.R283K (on ENST00000357365 / NM_001039707.2; = p.R260K on NM_006643.4) | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- EP400 | c.9058C>T p.P3020S | Missense Mutation (SNP) | VAF 196/452 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EPHB6 | c.2366G>A p.S789N | Missense Mutation (SNP) | VAF 359/1258 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EPYC | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 191/435 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERICH5 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 257/550 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ESPL1 | c.3307G>A p.G1103S | Missense Mutation (SNP) | VAF 234/538 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- EVC | c.2804G>A p.R935K | Missense Mutation (SNP) | VAF 143/303 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EVI5L | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 183/602 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- EXOC3L1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 171/552 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC4 | c.2564G>A p.G855D | Missense Mutation (SNP) | VAF 174/610 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- EXPH5 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FAM117A | c.1202G>A p.C401Y | Missense Mutation (SNP) | VAF 320/643 reads (50%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FAN1 | c.2561G>A p.G854E | Missense Mutation (SNP) | VAF 139/351 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FAT2 | c.7435C>T p.P2479S | Missense Mutation (SNP) | VAF 228/473 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXL17 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 403/819 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- FBXO31 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 411/865 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL5 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 136/279 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- FGF5 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 267/537 reads (50%) | called by muse, mutect2, varscan2
- FGGY | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 163/335 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FLG | c.10280C>T p.S3427F | Missense Mutation (SNP) | VAF 165/425 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLG2 | c.4054G>A p.D1352N | Missense Mutation (SNP) | VAF 245/513 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- FLNB | c.2264G>A p.S755N | Missense Mutation (SNP) | VAF 122/307 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- FN3KRP | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 164/346 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FPR3 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 211/700 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FRMD1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 137/310 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FRMD6 | c.749G>A p.G250E (on ENST00000344768 / NM_001267046.2; = p.G242E on NM_152330.4) | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRYL | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FSIP2 | c.9991G>A p.E3331K | Missense Mutation (SNP) | VAF 148/347 reads (43%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FUNDC2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- GAD1 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- GALNT14 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 156/296 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT5 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 171/368 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAN | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 212/462 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GAS8 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 166/363 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- GBP5 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GCN1 | c.4951T>G p.L1651V | Missense Mutation (SNP) | VAF 153/349 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GDPD2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 248/249 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GJA5 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 235/538 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLI1 | c.3226C>T p.P1076S | Missense Mutation (SNP) | VAF 204/465 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GNS | c.795C>T p.N265= | Splice Region (SNP) | VAF 85/202 reads (42%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 74/390 reads (19%) | called by muse, varscan2
- GOLGB1 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GOT1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 186/187 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR137C | c.629G>A p.S210N | Missense Mutation (SNP) | VAF 192/437 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- GTF2I | c.2597G>A p.R866K (on ENST00000573035 / NM_032999.4; = p.R825K on NM_001518.5) | Missense Mutation (SNP) | VAF 76/718 reads (11%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- HAS2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 151/337 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAUS1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR3 | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 141/313 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- HEATR5B | c.4397C>T p.P1466L | Missense Mutation (SNP) | VAF 193/193 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HEG1 | c.3517+1G>A p.X1173_splice | Splice Site (SNP) | VAF 113/244 reads (46%) | called by muse, mutect2, varscan2
- HIVEP1 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 183/410 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- HLA-E | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 95/237 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HMX1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 334/662 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPF | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 183/184 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- HSD17B3 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 174/424 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSF4 | c.751G>T p.G251C (on ENST00000521374 / NM_001040667.3; = p.W255C on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/600 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSP90AB1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 183/416 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSP90AB1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 169/387 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HSPG2 | c.2195+1G>A p.X732_splice | Splice Site (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2
- HTR3D | c.1150G>T p.E384* (on ENST00000382489 / NM_001163646.2; = p.E209* on NM_182537.3) | Nonsense Mutation (SNP) | VAF 203/401 reads (51%) | called by muse, mutect2, varscan2
- HUWE1 | c.7168C>T p.L2390F | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- IARS1 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 130/292 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ICAM4 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 213/751 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IDE | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 248/249 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IFT52 | c.768G>A p.E256= | Splice Region (SNP) | VAF 137/459 reads (30%) | called by muse, mutect2, varscan2
- IGHV3-35 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 161/344 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV3-49 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 156/351 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- IGLV4-3 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 191/632 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- IGSF9B | c.4295G>A p.G1432E | Missense Mutation (SNP) | VAF 155/325 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- IMPG1 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 109/245 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2
- INCENP | c.2202G>A p.E734= (on ENST00000394818 / NM_001040694.2; = p.E730= on NM_020238.3) | Splice Region (SNP) | VAF 265/570 reads (46%) | called by muse, mutect2, varscan2
- INF2 | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IPO8 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IPO8 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IQGAP2 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 157/325 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ITCH | c.1447G>A p.G483S (on ENST00000262650 / NM_001257137.3; = p.G442S on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/429 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ITGA2 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 112/291 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ITK | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 170/399 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2896C>T p.H966Y | Missense Mutation (SNP) | VAF 244/574 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KATNIP | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 228/462 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KCNG1 | c.1188_1198del p.Y396* | Nonsense Mutation (DEL) | VAF 270/885 reads (31%) | called by mutect2, pindel, varscan2
- KCNH7 | c.1441G>A p.V481M | Missense Mutation (SNP) | VAF 183/378 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIF21A | c.4319G>A p.S1440N (on ENST00000361418 / NM_001378440.1; = p.S1427N on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/300 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KMT2C | c.1813+1G>A p.X605_splice | Splice Site (SNP) | VAF 111/355 reads (31%) | called by muse, mutect2, varscan2
- KRT14 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KTN1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 154/350 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- KTN1 | c.1787C>T p.T596I | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- LAMA1 | c.3657G>A p.W1219* | Nonsense Mutation (SNP) | VAF 220/459 reads (48%) | called by muse, mutect2, varscan2
- LEPR | c.1536G>A p.W512* | Nonsense Mutation (SNP) | VAF 141/367 reads (38%) | called by muse, mutect2, varscan2
- LILRB1 | c.1786G>A p.E596K (on ENST00000427581; = p.E546K on NM_006669.6) | Missense Mutation (SNP) | VAF 201/683 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LINC00514 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 180/425 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.05); called by muse, varscan2
- LMNB1 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LMNB1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LNX1 | c.1892+1G>A p.X631_splice (on ENST00000263925 / NM_001126328.3; = p.X535_splice on NM_032622.2) | Splice Site (SNP) | VAF 172/298 reads (58%) | called by muse, mutect2, varscan2
- LRP1B | c.10843G>T p.G3615* | Nonsense Mutation (SNP) | VAF 95/244 reads (39%) | called by muse, mutect2, varscan2
- LRRC37A2 | c.3973C>T p.P1325S | Missense Mutation (SNP) | VAF 262/1281 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRRC7 | c.355C>T p.L119F (on ENST00000651989 / NM_001370785.2; = p.L86F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRN1 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 208/429 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LTA4H | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 144/324 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6L | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 184/393 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LYST | c.6842G>A p.G2281D | Missense Mutation (SNP) | VAF 106/231 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MAGEC1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 288/288 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MAGEC1 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 199/202 reads (99%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.321); called by muse, varscan2
- MAGEE2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 203/203 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MAN2B1 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 397/1236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K3 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K7 | c.1495G>A p.A499T (on ENST00000369329 / NM_145331.3; = p.A472T on NM_003188.4) | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAPRE1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED23 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 159/332 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MED24 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 325/656 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MEGF8 | c.6887G>A p.G2296D (on ENST00000251268 / NM_001271938.2; = p.G2229D on NM_001410.3) | Missense Mutation (SNP) | VAF 175/556 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MFSD12 | c.621C>A p.D207E | Missense Mutation (SNP) | VAF 281/936 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MGAT5B | c.2300C>T p.S767F (on ENST00000569840 / NM_001199172.2; = p.S765F on NM_144677.3) | Missense Mutation (SNP) | VAF 317/670 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MIER3 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- MKRN1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 149/534 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MLLT6 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 182/416 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MMP16 | c.16T>A p.F6I | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MNT | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 344/703 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); called by muse, mutect2
- MPRIP | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 156/328 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MSH4 | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCH1 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 188/399 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MTERF3 | c.677+1G>A p.X226_splice | Splice Site (SNP) | VAF 108/242 reads (45%) | called by muse, mutect2, varscan2
- MTMR12 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 113/273 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- MTPAP | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MUC16 | c.12815C>T p.T4272I | Missense Mutation (SNP) | VAF 216/587 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, varscan2
- MUC17 | c.2240C>G p.T747S | Missense Mutation (SNP) | VAF 162/531 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, varscan2
- MYEOV | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 266/571 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- MYH2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 125/253 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MYL12A | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 137/355 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MYLK2 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 172/602 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MYO1B | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 100/189 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MYOF | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 104/105 reads (99%) | called by muse, mutect2, varscan2
- NARS2 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 107/231 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NBPF26 | c.2705A>C p.Y902S (on ENST00000620612; = p.Y640S on NM_001351372.1) | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NCL | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 173/449 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- NDUFA1 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 111/112 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NEO1 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 120/310 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NFATC3 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 147/350 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- NFE2L2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 204/499 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NFE2L3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 455/1389 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NHLRC2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKAIN4 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 286/1208 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- NLN | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 92/254 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- NLRC3 | c.3028C>A p.Q1010K | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NLRP2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NOP53 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 140/463 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NSD2 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 188/662 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP205 | c.4990G>A p.D1664N | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- OGFR | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 222/633 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OMD | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 196/409 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- OOSP4B | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10K1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 219/427 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H6 | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 122/266 reads (46%) | called by muse, mutect2, varscan2
- OR4D11 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 188/390 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- OR51A2 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 180/236 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, varscan2
- OR5T1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD7A | c.826G>A p.E276K (on ENST00000307050 / NM_001382637.1; = p.E269K on NM_130901.3) | Missense Mutation (SNP) | VAF 293/608 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OVOL2 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 439/1365 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PAFAH1B1 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 193/375 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK3 | c.991G>A p.V331I (on ENST00000262836 / NM_001324328.2; = p.V316I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/86 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- PARP1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- PARP2 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 249/520 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PATJ | c.3577G>A p.G1193R | Missense Mutation (SNP) | VAF 131/286 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PCARE | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 172/347 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDHA6 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 211/393 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PCDHGA8 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 182/354 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCDHGC5 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 240/544 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCED1B | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 335/727 reads (46%) | called by muse, mutect2, varscan2
- PDHA2 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 203/487 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PDS5A | c.3526C>T p.P1176S | Missense Mutation (SNP) | VAF 154/367 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PER1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 210/445 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PGK2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 153/360 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGR | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 450/971 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PGRMC2 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 123/255 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PIGG | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3C3 | c.1386_1389del p.E464Ffs*15 | Frame Shift Del (DEL) | VAF 117/308 reads (38%) | called by mutect2, pindel, varscan2
- PKD1 | c.12289G>A p.G4097S (on ENST00000262304 / NM_001009944.3; = p.G4096S on NM_000296.4) | Missense Mutation (SNP) | VAF 379/815 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PKHD1L1 | c.8414-1G>A p.X2805_splice | Splice Site (SNP) | VAF 107/201 reads (53%) | called by muse, mutect2, varscan2
- PLK1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 189/414 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- PLXNA1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 279/584 reads (48%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 291/580 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- PNPLA6 | c.2632G>A p.G878S (on ENST00000414982 / NM_001166111.2; = p.G830S on NM_006702.5) | Missense Mutation (SNP) | VAF 203/680 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLH | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 133/302 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- POSTN | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 154/155 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPDPF | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 424/1673 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PPFIA2 | c.2171C>T p.T724I | Missense Mutation (SNP) | VAF 176/388 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPFIA2 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 123/310 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPFIA3 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 169/574 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PRKCSH | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 321/974 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROM1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 207/461 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PROM1 | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 54/120 reads (45%) | called by muse, mutect2, varscan2
- PSMA5 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTAR1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 145/317 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PTPN11 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 233/452 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTPRQ | c.1259C>T p.T420I (on ENST00000616559; = p.T378I on NM_001145026.2) | Missense Mutation (SNP) | VAF 176/413 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRS | c.5536G>A p.E1846K | Missense Mutation (SNP) | VAF 222/710 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PWWP3B | c.90del p.R31Gfs*7 | Frame Shift Del (DEL) | VAF 216/300 reads (72%) | called by mutect2, pindel, varscan2
- PYCR1 | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 257/528 reads (49%) | called by muse, mutect2, varscan2
- QRSL1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 121/316 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- QTRT1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 356/970 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB28 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 133/332 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- RAPGEF2 | c.371-1G>A p.X124_splice | Splice Site (SNP) | VAF 115/236 reads (49%) | called by muse, mutect2, varscan2
- RBBP6 | c.3475G>A p.D1159N | Missense Mutation (SNP) | VAF 163/358 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RBM26 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 211/212 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- RBPJ | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 172/347 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCC1 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 156/357 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCN1 | c.836A>T p.D279V | Missense Mutation (SNP) | VAF 136/356 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- REV3L | c.6061A>G p.K2021E | Missense Mutation (SNP) | VAF 212/418 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RFPL4AL1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 120/947 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RFPL4AL1 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, varscan2
- RFPL4AL1 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); called by muse, varscan2
- RGS12 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 235/529 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RGS20 | c.685C>T p.Q229* (on ENST00000297313 / NM_170587.4; = p.Q82* on NM_003702.4) | Nonsense Mutation (SNP) | VAF 172/189 reads (91%) | called by muse, mutect2, varscan2
- RIF1 | c.2792G>A p.S931N | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- RIMBP3 | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RIMBP3 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by mutect2, varscan2
- RIMBP3 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 180/845 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RMND5A | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 115/235 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RNASEH1 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 222/479 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF217 | c.1148G>A p.C383Y (on ENST00000521654 / NM_001286398.2; = p.C91Y on NM_152553.5) | Missense Mutation (SNP) | VAF 146/338 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RNF43 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 205/426 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ROBO2 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 130/313 reads (42%) | called by muse, mutect2, varscan2
- ROCK1 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL23A | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- RPUSD2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 252/521 reads (48%) | called by muse, mutect2, varscan2
- RRM1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 105/208 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RSBN1 | c.1976G>A p.R659K | Missense Mutation (SNP) | VAF 151/358 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SAFB2 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 210/664 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SASS6 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF1 | c.3139G>A p.A1047T | Missense Mutation (SNP) | VAF 382/1218 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- SEC16A | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 266/554 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SEC16A | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 197/399 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- SEL1L2 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 169/561 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SEMA3C | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 111/451 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SEMA3F | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 179/384 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SGCB | c.753+1G>A p.X251_splice | Splice Site (SNP) | VAF 95/193 reads (49%) | called by muse, mutect2, varscan2
- SH2D4B | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 183/183 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- SHISA6 | c.1477G>A p.A493T (on ENST00000409168 / NM_001173461.1; = p.A544T on NM_207386.4) | Missense Mutation (SNP) | VAF 204/458 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SIGIRR | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 185/421 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SIGLEC9 | c.1107-1G>A p.X369_splice | Splice Site (SNP) | VAF 80/245 reads (33%) | called by muse, mutect2, varscan2
- SLC19A3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 236/475 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC1A2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 224/412 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC1A4 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 493/983 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A5 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 170/171 reads (99%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC26A3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 128/446 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SLC30A5 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SLC34A1 | c.1175-1G>A p.X392_splice | Splice Site (SNP) | VAF 137/278 reads (49%) | called by muse, mutect2, varscan2
- SLC41A1 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 237/534 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A9 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 194/420 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SLCO1A2 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 179/381 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SMC6 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMG6 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 192/400 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMG8 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 241/501 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMIM13 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 292/617 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SMOX | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 227/726 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SNED1 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 271/595 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SNRPB2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SNRPC | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 205/427 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SNTA1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 122/402 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SNX27 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX9 | c.801del p.I268Sfs*11 | Frame Shift Del (DEL) | VAF 312/785 reads (40%) | called by mutect2, pindel, varscan2
- SP1 | c.2063G>A p.C688Y (on ENST00000327443 / NM_138473.3; = p.C681Y on NM_003109.1) | Missense Mutation (SNP) | VAF 158/328 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPAM1 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 169/560 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA16 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 182/379 reads (48%) | called by muse, mutect2, varscan2
- SPATA21 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 213/1032 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA5L1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 171/381 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SPEG | c.6241G>A p.D2081N | Missense Mutation (SNP) | VAF 507/991 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SPHK2 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 382/1093 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPTBN4 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 211/605 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- SRMS | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 324/1445 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, varscan2
- ST6GALNAC1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 237/509 reads (47%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ST7L | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ST8SIA1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 212/426 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD6 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- STK32B | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.058); called by muse, mutect2
- STN1 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- STRC | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 265/1143 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- STX19 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 148/338 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUGCT | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUSD4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 205/435 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SYCP2 | c.2716G>A p.V906I | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYNE2 | c.7435G>A p.E2479K | Missense Mutation (SNP) | VAF 230/459 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNPO | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 327/639 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SYT10 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 137/280 reads (49%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- TAAR2 | c.1025C>T p.T342I (on ENST00000367931 / NM_001033080.1; = p.T297I on NM_014626.3) | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, varscan2
- TAB2 | c.1619A>G p.Q540R | Missense Mutation (SNP) | VAF 96/196 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TBX3 | c.1750C>T p.Q584* (on ENST00000257566 / NM_016569.4; = p.Q564* on NM_005996.4) | Nonsense Mutation (SNP) | VAF 280/598 reads (47%) | called by muse, mutect2, varscan2
- TCEA2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 188/611 reads (31%) | called by muse, mutect2, varscan2
- TCOF1 | c.1612G>A p.V538M (on ENST00000377797 / NM_001135243.1; = p.V461M on NM_000356.4) | Missense Mutation (SNP) | VAF 284/625 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TEAD3 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 311/671 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TENM2 | c.3265C>T p.Q1089* (on ENST00000518659 / NM_001122679.2; = p.Q857* on NM_001080428.3) | Nonsense Mutation (SNP) | VAF 213/538 reads (40%) | called by muse, mutect2, varscan2
- TGFBR3L | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 397/1241 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TLR5 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 164/401 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TM2D1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TMEM147 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 199/694 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM39B | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 142/251 reads (57%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPRSS11E | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 188/393 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFRSF10A | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 107/257 reads (42%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- TNFSF9 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 369/1241 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TPR | c.5776G>A p.D1926N | Missense Mutation (SNP) | VAF 212/427 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TPX2 | c.1153A>G p.S385G | Missense Mutation (SNP) | VAF 208/640 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TRBJ2-6 | c.3C>T p.*1= | Missense Mutation (SNP) | VAF 355/1071 reads (33%) | called by muse, mutect2, varscan2
- TRIB3 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 353/1084 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRPV4 | c.2030C>T p.T677I | Missense Mutation (SNP) | VAF 297/600 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TSC22D2 | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 283/581 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TTF1 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTN | c.78730G>A p.E26244K (on ENST00000591111; = p.E18820K on NM_003319.4) | Missense Mutation (SNP) | VAF 141/305 reads (46%) | PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TTN | c.61198C>T p.P20400S (on ENST00000591111; = p.P12976S on NM_003319.4) | Missense Mutation (SNP) | VAF 166/395 reads (42%) | PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TUBA3D | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 187/455 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- TXNDC11 | c.1358C>T p.T453I (on ENST00000356957 / NM_001303447.2; = p.T426I on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 303/588 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- UBE3A | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 198/410 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- UBR1 | c.1850G>A p.G617D | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT2B7 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- UROS | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USB1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 213/456 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- USH2A | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 194/429 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USP25 | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- USP26 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- USP34 | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 166/351 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- VGF | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 330/977 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- VPS13C | c.4805C>T p.T1602I (on ENST00000644861 / NM_020821.3; = p.T1559I on NM_017684.5) | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSX2 | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 159/327 reads (49%) | called by muse, mutect2, varscan2
- VWF | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 202/420 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASHC5 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDR73 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 112/204 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WHAMM | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 212/447 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
416 further variants in this file (31 protein-altering or splice-affecting, 349 silent, 36 other) are not listed here.
